Gene-level copy-number profile of tumor specimen ALCH-B1YS-TTP1-A from ALCHEMIST case ALCH-B1YS, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.2 years (21,620 days).
Specimen ALCH-B1YS-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9979bbf0-05e3-4811-bcc6-a29f478a4ad7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1YS-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/8cd6b34d-5c36-4763-838c-c420b4971333

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 555; copy number 1: 16,815; copy number 2: 35,533; copy number 3: 4,822; copy number 4: 740; copy number 5: 426; copy number 6: 1; copy number 9: 10; copy number 135: 2; copy number 253: 1.

Homozygous deletions (total copy number 0; autosomes only): 43 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,659,121–39,672,038, 1 gene: NT5C1A.
- chr3:75,370,448–75,391,810, 2 genes: OR7E55P, AC139453.2.
- chr3:75,415,070–75,422,143, 1 gene (within-gene range 0–2): ALG1L6P.
- chr3:75,435,232–75,538,029, 3 genes: LINC02018, ENPP7P2, SNRPCP10.
- chr3:75,542,149–75,542,929, 1 gene (within-gene range 0–1): RPS3AP15.
- chr3:75,598,652–75,670,185, 10 genes: OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26.
- chr3:123,282,296–123,449,090, 2 genes (within-gene range 0–2): ADCY5, AC112503.1.
- chr7:154,838,388–154,865,483, 1 gene (within-gene range 0–2): AC073336.1.
- chr12:130,138,693–130,165,740, 4 genes: AC026336.3, FZD10-AS1, AC026336.5, FZD10.
- chr15:52,755,053–52,791,078, 1 gene: ONECUT1.
- chr18:37,273,706–37,276,572, 1 gene (within-gene range 0–2): AC090386.1.
- chr19:33,299,934–33,305,054, 4 genes (within-gene range 0–2): AC008738.3, CEBPA, AC008738.5, CEBPA-DT.
- chr22:26,858,634–26,968,763, 1 gene (within-gene range 0–2): LINC01422.
- chr22:26,903,292–26,920,935, 1 gene: Z97353.2.
- chr22:30,262,829–30,276,951, 2 genes: OSM, AC004264.2.
- chr22:30,554,635–30,574,665, 1 gene: GAL3ST1.
- chr22:30,635,781–30,674,134, 4 genes: SLC35E4, DUSP18, AC003072.1, AC003072.2.
- chr22:30,922,308–30,968,774, 2 genes: MORC2-AS1, MORC2.
- chr22:41,576,900–41,589,871, 1 gene (within-gene range 0–1): PMM1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 440 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,578,473–128,220,803, 15 genes, copy number 5–253: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr17:39,619,613–39,622,770, 1 gene, copy number 5: AC087491.1.
- chr17:39,667,981–39,670,475, 1 gene, copy number 5: PNMT.
- chr20:6,731,080–26,251,546, 336 genes, copy number 5 (broad region; genes not listed).
- chr20:30,484,925–33,243,311, 87 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,471. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
